CCDI case PBBYHL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ba25b640-e417-4c65-9bdf-5d3c8c77e27b

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (429 days).

Biospecimens (2 samples)
- Sample 0DLHOF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLHOW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
